Gene-level copy-number profile of tumor specimen AP-JK59-NN from APOLLO case AP-JK59, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3.
Specimen AP-JK59-NN: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a6dba353-ef70-4552-bcfa-2fb06f2f62ad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-JK59-FL (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/e7f4124e-c629-4684-9e84-7b51742623dc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 116; copy number 1: 9,261; copy number 2: 45,774; copy number 3: 3,176; copy number 4: 59; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 116 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,202,316–90,261,708, 2 genes: PROS2P, HSPE1P19.
- chr4:49,203,171–49,589,529, 19 genes: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr6:61,240,898–61,241,311, 1 gene: AL356131.1.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr9:6,542,094–6,727,438, 9 genes (within-gene range 0–1): RN7SL25P, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1.
- chr9:6,734,598–6,748,981, 2 genes (within-gene range 0–1): PRELID3BP11, SNRPEP2.
- chr9:19,089,593–19,201,046, 3 genes (within-gene range 0–1): Y_RNA, PLIN2, AL161909.1.
- chr9:65,189,995–65,323,015, 6 genes: BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.
- chr11:48,579,436–48,951,895, 9 genes: OR4A45P, OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP.
- chr11:54,591,480–55,271,114, 13 genes: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P, TRIM48, AP005597.4.
- chr12:37,575,587–38,087,392, 3 genes: ZNF970P, AK6P2, CLUHP8.
- chr16:32,278,866–32,478,250, 9 genes: AC140878.1, AC133548.2, AC133548.1, ACTR3BP3, AC138915.2, PABPC1P13, AC138915.3, AC138915.1, ABCD1P3.
- chr21:7,744,962–9,018,670, 37 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:57,495,966–57,568,121, 2 genes, copy number 5: CTCFL, PCK1.

Autosomal genes at a single copy (total copy number 1): 7,371. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
